Gene-level copy-number profile of tumor specimen TCGA-77-7338-01A from TCGA case TCGA-77-7338, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.3 years (23,480 days).
Specimen TCGA-77-7338-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.f6469547-7a14-4d75-aa91-d45a455693a6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-7338-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1a2f9d9a-d1f2-42c1-8fcb-7faea5fe2e65

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15,448; copy number 2: 37,286; copy number 3: 5,926; copy number 4: 211; copy number 5: 142; copy number 6: 169; copy number 7: 562; copy number 8: 67.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-7338-01A-11D-2041-01): tumor purity 0.52, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 940 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:207,496,147–208,270,667, 19 genes, copy number 6 (within-gene range 3–6): CR1, AL137789.1, CR1L, CD46P1, CDCA4P3, RNA5SP534, AL137789.2, CD46, CDCA4P4, MIR29B2CHG, MIR29C, MIR29B2, CD34, AL356275.1, LINC02767, PLXNA2, AL590138.1, AL606753.1, AL606753.2.
- chr2:177,227,595–177,392,697, 1 gene, copy number 5 (within-gene range 2–8): NFE2L2.
- chr2:177,255,945–177,392,691, 9 genes, copy number 5–8: MIR3128, AC079305.1, AC019080.1, AC019080.3, AC019080.4, MIR6512, AC019080.5, H3P7, AC019080.2.
- chr3:147,386,046–198,222,513, 911 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,062. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
